Somatic mutation profile of tumor specimen MMRF_2106_1_BM_CD138pos (aliquot MMRF_2106_1_BM_CD138pos_T1_KHS5U_L08664) from MMRF case MMRF_2106, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 54.6 years (19,958 days).
Specimen MMRF_2106_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b758152-f9ce-42be-9fe5-888025eee7c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2106_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_2106_1_PB_CD3pos_C2_KHS5U_L08665; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8baaee95-a124-4f52-ba00-585ecf81338b

The open-access MAF lists 117 somatic variants for this specimen: 53 protein-altering or splice-affecting, 12 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, 3'UTR 26, Silent 12, Intron 9, 5'UTR 8, 3'Flank 4, RNA 3, Nonsense Mutation 3, Splice Site 3, 5'Flank 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 15/156 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- NRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 24/113 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ATP2B4 | c.997G>C p.D333H | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.277); catalogued as rs200430665, COSV100397153; called by mutect2, varscan2
- CDKN2B | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs762253433, COSV52805866; called by muse, mutect2, varscan2
- CSMD1 | c.6832G>A p.E2278K (on ENST00000520002; = p.E2277K on NM_033225.6) | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.988); catalogued as rs763832031, COSV59383429; called by mutect2, varscan2
- DENND4C | c.802-2A>T p.X268_splice | Splice Site (SNP) | VAF 6/104 reads (6%) | catalogued as COSV66821841; called by muse, mutect2
- EP400 | c.4229C>T p.S1410L | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as COSV57775905; called by muse, mutect2, varscan2
- FOXRED2 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs767266488; called by mutect2, varscan2
- GPT2 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0.017); catalogued as rs1250840020; called by muse, mutect2, varscan2
- IAH1 | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.237); catalogued as rs770978412; called by muse, mutect2, varscan2
- IL18R1 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.297); catalogued as rs559291188, COSV52123188; called by muse, mutect2, varscan2
- INO80 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as COSV99054981; called by muse, mutect2, varscan2
- INTS1 | c.1409C>T p.S470L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as rs1021169834; called by muse, mutect2, varscan2
- KIF26B | c.5667C>G p.F1889L | Missense Mutation (SNP) | VAF 16/427 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.31); catalogued as COSV63649935; called by muse, mutect2
- LLCFC1 | c.419G>A p.R140Q (on ENST00000458732; = p.R109Q on NM_178829.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.043); catalogued as rs997248326, COSV62338829; called by muse, mutect2, varscan2
- MXRA5 | c.4825C>G p.P1609A | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV54231696; called by muse, mutect2, varscan2
- MYC | c.548C>T p.A183V (on ENST00000377970; = p.A198V on NM_002467.6) | Missense Mutation (SNP) | VAF 70/369 reads (19%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); catalogued as COSV52382855; called by muse, varscan2
- NPY5R | c.1231C>T p.H411Y | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765532392; called by muse, mutect2, varscan2
- OR4C13 | c.569C>T p.T190I | Missense Mutation (SNP) | VAF 15/299 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.654); catalogued as COSV73648692; called by muse, mutect2
- PCLO | c.1699C>G p.L567V | Missense Mutation (SNP) | VAF 17/192 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV61661130; called by muse, mutect2
- PTCHD3 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.599); catalogued as rs762103687, COSV71256468; called by muse, mutect2, varscan2
- SHLD2 | c.2050C>G p.L684V | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV53953010; called by muse, mutect2, varscan2
- SYNGR4 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as rs201450222; called by muse, mutect2, varscan2
- ZNF275 | c.362G>A p.R121K | Missense Mutation (SNP) | VAF 5/122 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.285); catalogued as COSV64704425; called by muse, mutect2
- CCR9 | c.1103C>T p.S368F (on ENST00000357632 / NM_031200.3; = p.S356F on NM_006641.4) | Missense Mutation (SNP) | VAF 47/273 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DCHS2 | c.965A>G p.D322G | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- DHFR | c.369G>C p.K123N | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); called by muse, mutect2
- DRAP1 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- EIF3G | c.624C>G p.N208K | Missense Mutation (SNP) | VAF 40/201 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FAT3 | c.2524G>C p.E842Q | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IRAG1 | c.1571+1G>A p.X524_splice | Splice Site (SNP) | VAF 13/139 reads (9%) | called by muse, mutect2
- IRGC | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- KIF20B | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by mutect2, varscan2
- LPA | c.3371A>T p.E1124V | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- MAP2K2 | c.306G>A p.L102= | Splice Region (SNP) | VAF 18/258 reads (7%) | called by muse, mutect2
- MDN1 | c.10510C>G p.L3504V | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MXRA5 | c.4826C>T p.P1609L | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- NEXMIF | c.541G>C p.D181H | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by mutect2, varscan2
- OR52E2 | c.6C>A p.F2L | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); called by muse, mutect2
- OSBPL8 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 44/381 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- PAIP2 | c.139-1G>A p.X47_splice | Splice Site (SNP) | VAF 26/130 reads (20%) | called by muse, mutect2
- POM121 | c.323C>A p.S108* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- SETD1A | c.3974C>T p.A1325V | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- SYCP1 | c.599A>T p.Y200F | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TAF3 | c.434C>T p.T145I | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- TBC1D9 | c.3482C>T p.S1161F | Missense Mutation (SNP) | VAF 17/181 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TDRD10 | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 32/561 reads (6%) | called by muse, mutect2
- TICAM1 | c.1419G>C p.M473I | Missense Mutation (SNP) | VAF 50/358 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- UNC13A | c.4075C>A p.L1359M | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VWA8 | c.980C>T p.S327F | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- WIZ | c.2663C>G p.S888C (on ENST00000673675 / NM_001371589.1; = p.S151C on NM_021241.3) | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ZNF433 | c.150G>A p.W50* | Nonsense Mutation (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- ZNF83 | c.475C>T p.H159Y | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.18); called by mutect2, varscan2
- ADCY2 | c.2676C>A p.S892= | Silent (SNP) | VAF 9/68 reads (13%) | called by muse, mutect2, varscan2
- BPIFB3 | c.858C>T p.L286= | Silent (SNP) | VAF 44/170 reads (26%) | called by muse, varscan2
- CDO1 | c.21G>T p.L7= | Silent (SNP) | VAF 8/149 reads (5%) | called by muse, mutect2
- CSK | c.177C>T p.I59= | Silent (SNP) | VAF 9/147 reads (6%) | catalogued as rs1446585731; called by muse, mutect2
- ERCC3 | c.1365C>T p.L455= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as rs781680348; called by muse, mutect2, varscan2
- MDGA2 | c.1434C>T p.F478= (on ENST00000399232 / NM_001113498.2; = p.F180= on NM_182830.4) | Silent (SNP) | VAF 11/345 reads (3%) | called by muse, mutect2
- PROB1 | c.144G>A p.P48= | Silent (SNP) | VAF 13/52 reads (25%) | called by muse, mutect2, varscan2
- PSD | c.1503T>C p.S501= | Silent (SNP) | VAF 26/127 reads (20%) | called by muse, mutect2, varscan2
- RAVER1 | c.1170G>A p.Q390= | Silent (SNP) | VAF 17/86 reads (20%) | called by muse, mutect2, varscan2
- TAS2R41 | c.342C>T p.I114= | Silent (SNP) | VAF 45/175 reads (26%) | called by muse, mutect2, varscan2
- TRIM32 | c.699G>A p.V233= | Silent (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
- TTC36 | c.393C>T p.L131= | Silent (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2, varscan2
- A2M | c.4408+164C>G | Intron (SNP) | VAF 19/76 reads (25%) | called by muse, mutect2, varscan2
- AC132217.2 | c.*25G>T | 3'UTR (SNP) | VAF 16/58 reads (28%) | called by muse, mutect2, varscan2
- AC244394.2 | n.772A>C | RNA (SNP) | VAF 18/380 reads (5%) | called by muse, mutect2
- ACTN2 | c.*1305G>A | 3'UTR (SNP) | VAF 9/102 reads (9%) | called by muse, mutect2
- ANOS1 | c.*280C>T | 3'UTR (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2, varscan2
- ATM | c.*1979G>A | 3'UTR (SNP) | VAF 24/112 reads (21%) | called by muse, varscan2
- BEND4 | c.-170G>A | 5'UTR (SNP) | VAF 17/59 reads (29%) | called by muse, mutect2, varscan2
- BRWD1 | c.6572-3729C>T | Intron (SNP) | VAF 46/130 reads (35%) | called by mutect2, varscan2
- C4orf50 | c.-309C>G | 5'UTR (SNP) | VAF 48/166 reads (29%) | called by muse, mutect2, varscan2
- CALM3 | c.*1398G>C | 3'UTR (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2, varscan2
- CAMK1D | c.*5004C>T | 3'UTR (SNP) | VAF 5/28 reads (18%) | called by muse, mutect2, varscan2
- CAMTA2 | c.-37C>G | 5'UTR (SNP) | VAF 20/84 reads (24%) | catalogued as rs991497139, COSV61788891; called by muse, mutect2, varscan2
- CHCHD3 | c.369+1162C>T | Intron (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- DAO | c.912+33C>T | Intron (SNP) | VAF 15/60 reads (25%) | called by muse, mutect2
- ENTPD4 | c.*200G>A | 3'UTR (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- FAAH | c.785+87G>T | Intron (SNP) | VAF 10/53 reads (19%) | catalogued as rs1174825674; called by mutect2, varscan2
- FAM153CP | chr5:178055538 G>A | 3'Flank (SNP) | VAF 3/26 reads (12%) | catalogued as rs955911648; called by muse, mutect2
- FAM8A1 | c.*375G>A | 3'UTR (SNP) | VAF 4/16 reads (25%) | catalogued as rs200864954; called by muse, mutect2
- HHIP | c.*251C>G | 3'UTR (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2, varscan2
- HMGCR | c.*802C>T | 3'UTR (SNP) | VAF 39/208 reads (19%) | called by muse, mutect2, varscan2
- HOXD3 | chr2:176174887 G>A | 3'Flank (SNP) | VAF 22/57 reads (39%) | called by muse, mutect2, varscan2
- IFT172 | c.403-92C>T | Intron (SNP) | VAF 5/92 reads (5%) | catalogued as rs1418363745; called by muse, mutect2
- IPO5 | c.-134G>A | 5'UTR (SNP) | VAF 9/200 reads (5%) | catalogued as COSV55156366; called by muse, mutect2
- KCTD17 | c.210+245G>A | Intron (SNP) | VAF 9/28 reads (32%) | called by muse, mutect2, varscan2
- MAT2A | c.-45C>T | 5'UTR (SNP) | VAF 19/68 reads (28%) | catalogued as rs778900933; called by muse, mutect2, varscan2
- MIR4444-2 | n.65C>T | RNA (SNP) | VAF 9/44 reads (20%) | catalogued as rs776713152; called by muse, mutect2
- MPPED2 | c.*537G>A | 3'UTR (SNP) | VAF 18/76 reads (24%) | catalogued as rs1351059387; called by muse, mutect2, varscan2
- MRAS | c.*2544G>A | 3'UTR (SNP) | VAF 32/181 reads (18%) | called by muse, mutect2, varscan2
- NAA15 | c.*1670C>G | 3'UTR (SNP) | VAF 35/120 reads (29%) | called by muse, mutect2, varscan2
- NFYC-AS1 | n.210G>C | RNA (SNP) | VAF 31/186 reads (17%) | called by muse, mutect2, varscan2
- NOS1 | c.-385G>C | 5'UTR (SNP) | VAF 20/113 reads (18%) | called by muse, mutect2, varscan2
- PCDHB11 | c.*674G>A | 3'UTR (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2, varscan2
- PIK3C3 | c.*2215G>A | 3'UTR (SNP) | VAF 17/91 reads (19%) | called by muse, mutect2, varscan2
- RAB40C | chr16:629689 C>A | 3'Flank (SNP) | VAF 22/116 reads (19%) | called by muse, mutect2, varscan2
- RAD23B | chr9:107283159 C>G | 5'Flank (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2, varscan2
- RNFT2 | c.*35G>A | 3'UTR (SNP) | VAF 25/375 reads (7%) | called by muse, mutect2
- SCNM1 | c.*441G>C | 3'UTR (SNP) | VAF 16/130 reads (12%) | called by mutect2, varscan2
- SERINC5 | chr5:80256037 C>A | 5'Flank (SNP) | VAF 8/36 reads (22%) | catalogued as COSV72597142; called by muse, mutect2, varscan2
- SLC25A16 | c.-67C>A | 5'UTR (SNP) | VAF 13/49 reads (27%) | called by muse, mutect2, varscan2
- SORL1 | c.*242C>T | 3'UTR (SNP) | VAF 34/110 reads (31%) | called by muse, mutect2, varscan2
- SSU72 | c.224+1642C>G | Intron (SNP) | VAF 6/130 reads (5%) | called by muse, mutect2
- TENT5A | c.*3276G>A | 3'UTR (SNP) | VAF 22/133 reads (17%) | called by muse, mutect2, varscan2
- TENT5C | c.*2189G>A | 3'UTR (SNP) | VAF 22/74 reads (30%) | called by muse, mutect2, varscan2
- TMEM108 | c.*1329G>C | 3'UTR (SNP) | VAF 21/108 reads (19%) | called by muse, varscan2
- TMEM245 | c.*2689C>G | 3'UTR (SNP) | VAF 19/120 reads (16%) | called by muse, mutect2, varscan2
- TNFAIP8 | c.-484C>A | 5'UTR (SNP) | VAF 16/174 reads (9%) | called by muse, mutect2, varscan2
- TRIM67 | chr1:231217584 C>G | 3'Flank (SNP) | VAF 18/141 reads (13%) | catalogued as rs571067779; called by muse, mutect2, varscan2
- TTLL7 | c.*1431C>A | 3'UTR (SNP) | VAF 12/59 reads (20%) | called by muse, mutect2, varscan2
- USP31 | c.*1284C>A | 3'UTR (SNP) | VAF 12/69 reads (17%) | called by muse, mutect2, varscan2
- YIPF3 | c.395+345G>C | Intron (SNP) | VAF 15/93 reads (16%) | called by muse, mutect2, varscan2
- YIPF6 | c.*1533G>A | 3'UTR (SNP) | VAF 21/53 reads (40%) | called by muse, mutect2, varscan2
- YY2 | c.*394G>A | 3'UTR (SNP) | VAF 5/31 reads (16%) | catalogued as rs1484404104; called by muse, mutect2
